Somatic mutation profile of tumor specimen MMRF_1730_2_BM_CD138pos (aliquot MMRF_1730_2_BM_CD138pos_T1_KHS5U_L16540) from MMRF case MMRF_1730, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.8 years (18,560 days).
Specimen MMRF_1730_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37584ecc-40f9-490a-ae2f-6aa8f87a1939.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1730_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1730_1_PB_Whole_C3_KBS5U_L04799; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25573187-8777-4845-966e-5b67f5699ac3

The open-access MAF lists 78 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 14, Intron 10, Silent 10, 5'UTR 2, Nonsense Mutation 2, 5'Flank 2, RNA 1, 3'Flank 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACKR2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757492481; called by muse, mutect2, varscan2
- DCDC1 | c.5224G>T p.E1742* (on ENST00000597505 / NM_001367979.1; = p.E849* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as rs764146895, COSV100360827; called by muse, mutect2, varscan2
- DYNC2H1 | c.12776G>T p.G4259V | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs368203507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHJ5 | c.35T>A p.V12D | Missense Mutation (SNP) | VAF 36/60 reads (60%) | PolyPhen probably damaging (0.927); catalogued as rs368830933; called by muse, varscan2
- IGHV2-70 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs138836314; called by muse, varscan2
- IGHV2-70D | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1446744170; called by muse, varscan2
- IGHV4-34 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs11546814; called by muse, mutect2, varscan2
- INSYN2A | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV54743255; called by muse, mutect2, varscan2
- MKRN3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs140349866; called by muse, mutect2, varscan2
- MTUS2 | c.2792C>T p.T931I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1264442280; called by muse, mutect2, varscan2
- PACSIN3 | c.1160-1G>A p.X387_splice | Splice Site (SNP) | VAF 59/268 reads (22%) | catalogued as COSV54066400; called by muse, mutect2, varscan2
- PCSK6 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs757508987; called by muse, mutect2, varscan2
- PLEKHA6 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.09); catalogued as rs767307862, COSV55333127; called by muse, mutect2, varscan2
- RAD1 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs201689146; called by muse, mutect2, varscan2
- RPL6 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52517300; called by muse, mutect2
- TEX15 | c.6841C>A p.P2281T (on ENST00000256246; = p.P2664T on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV56351943; called by muse, mutect2, varscan2
- TSPOAP1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs754322033; called by muse, mutect2, varscan2
- BICRA | c.3246C>A p.A1082= | Splice Region (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- CASP5 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH23 | c.7339A>T p.K2447* | Nonsense Mutation (SNP) | VAF 56/226 reads (25%) | called by muse, mutect2, varscan2
- GNAI1 | c.770A>T p.K257M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IFT52 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, varscan2
- INSYN2A | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LACTB | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.2816G>A p.C939Y | Missense Mutation (SNP) | VAF 118/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATR3 | c.627A>C p.Q209H | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NLRP8 | c.2195G>A p.C732Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NOL11 | c.48C>A p.S16R | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- NRK | c.2054A>C p.K685T | Missense Mutation (SNP) | VAF 104/125 reads (83%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR7C1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDHB6 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTK6 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC26A9 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SON | c.283_297del p.V95_P99del | In Frame Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- TRPC4AP | c.1812C>G p.I604M | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.235); called by muse, varscan2
- UCKL1 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- USP47 | c.1484A>G p.H495R (on ENST00000399455 / NM_001372095.1; = p.H407R on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHMT2 | c.675T>C p.G225= | Silent (SNP) | VAF 49/187 reads (26%) | called by muse, mutect2, varscan2
- COL6A6 | c.2367T>C p.D789= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as rs750757392; called by muse, mutect2, varscan2
- GASK1B | c.501T>C p.A167= | Silent (SNP) | VAF 74/206 reads (36%) | called by muse, mutect2, varscan2
- GPR143 | c.702C>T p.N234= | Silent (SNP) | VAF 103/118 reads (87%) | catalogued as rs138339667; called by muse, mutect2, varscan2
- MFAP3L | c.987T>C p.H329= | Silent (SNP) | VAF 78/202 reads (39%) | called by muse, mutect2, varscan2
- MYH7B | c.2118G>A p.L706= | Silent (SNP) | VAF 99/927 reads (11%) | called by muse, varscan2
- NUP188 | c.4020C>T p.L1340= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1214282846; called by muse, mutect2, varscan2
- PNLIPRP2 | c.435G>C p.A145= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV53942252; called by muse, mutect2, varscan2
- SIGLEC5 | c.987C>G p.L329= | Silent (SNP) | VAF 60/237 reads (25%) | called by muse, mutect2, varscan2
- TXK | c.1278C>T p.A426= | Silent (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65501958 del AA | 5'Flank (DEL) | VAF 62/182 reads (34%) | catalogued as rs771833705; called by mutect2, pindel, varscan2
- CAV3 | c.*741G>A | 3'UTR (SNP) | VAF 73/172 reads (42%) | catalogued as rs560215660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP19 | c.*1256A>C | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- DAPK3 | c.*69C>T | 3'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as rs958800634; called by mutect2, varscan2
- DIP2C | c.85+37156G>A | Intron (SNP) | VAF 209/251 reads (83%) | called by muse, mutect2, varscan2
- DKK3 | c.*994G>A | 3'UTR (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- ELMO2 | c.808-920C>T | Intron (SNP) | VAF 12/112 reads (11%) | called by muse, varscan2
- ENPP1 | c.*3305C>T | 3'UTR (SNP) | VAF 38/52 reads (73%) | called by muse, mutect2, varscan2
- F2RL2 | c.*308C>T | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs753600254; called by muse, varscan2
- FAM24B | chr10:122846103 del GA | 3'Flank (DEL) | VAF 53/134 reads (40%) | called by mutect2, pindel, varscan2
- FBXO42 | c.*1281C>T | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- FRMD5 | c.*1289T>C | 3'UTR (SNP) | VAF 51/163 reads (31%) | called by muse, mutect2, varscan2
- FSD1L | c.*480G>A | 3'UTR (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- GATAD2B | c.*4518dup | 3'UTR (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- GRM7 | c.2452-43632T>G | Intron (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- HERPUD1 | c.906-56_906-53del | Intron (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- LTB | c.163-109T>C | Intron (SNP) | VAF 97/285 reads (34%) | called by muse, varscan2
- MIER1 | c.180+955T>A | Intron (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851212 T>G | 5'Flank (SNP) | VAF 103/234 reads (44%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.*1415T>G | 3'UTR (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
- PHEX | c.*3200T>C | 3'UTR (SNP) | VAF 36/42 reads (86%) | called by muse, mutect2, varscan2
- PHF20 | c.340+2013A>G | Intron (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- REL | c.-8G>C | 5'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- RPS15A | c.-5-9C>T | Intron (SNP) | VAF 204/508 reads (40%) | called by muse, mutect2, varscan2
- SCARA5 | c.1153+63C>A | Intron (SNP) | VAF 41/75 reads (55%) | catalogued as rs753362034; called by muse, mutect2, varscan2
- SDR16C6P | n.326G>A | RNA (SNP) | VAF 149/353 reads (42%) | called by muse, mutect2, varscan2
- SLC24A2 | c.-52A>G | 5'UTR (SNP) | VAF 82/271 reads (30%) | called by muse, mutect2, varscan2
- TTC9 | c.*2060G>A | 3'UTR (SNP) | VAF 38/101 reads (38%) | catalogued as rs904803963; called by muse, mutect2, varscan2
- ZHX3 | c.*4574C>T | 3'UTR (SNP) | VAF 24/226 reads (11%) | called by muse, mutect2
- ZNF425 | c.18+43G>A | Intron (SNP) | VAF 80/189 reads (42%) | called by muse, mutect2, varscan2
